Somatic mutation profile of tumor specimen 0DHMNW from CCDI case PBBUKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.2 years (799 days).
Specimen 0DHMNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f44a253a-e643-487e-9785-4a89868c4c7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHMLS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f86344e7-6545-44b4-a71c-929386584478

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MGAT4D | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 43/901 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1356548403; called by muse, mutect2
- RALGAPA2 | c.3293G>C p.R1098P | Missense Mutation (SNP) | VAF 222/898 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99175103; called by muse, mutect2, varscan2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 9/97 reads (9%) | called by muse, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, varscan2
